Gene-level copy-number profile of tumor specimen HTMCP-03-06-02003-01A from CGCI case HTMCP-03-06-02003, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Dead; Primary diagnosis: Squamous cell carcinoma, nonkeratinizing, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IB2; Tumor grade: G2.
Specimen HTMCP-03-06-02003-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file aa660a6a-33f5-49e7-a218-35a86f36b3a3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HTMCP-03-06-02003-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,259 have no estimate.
https://portal.gdc.cancer.gov/files/a2f4a218-bf56-40a8-99ab-d8309ed28e90

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 3; copy number 1: 685; copy number 2: 11,920; copy number 3: 23,544; copy number 4: 18,690; copy number 5: 1,597; copy number 6: 1,412; copy number 7: 17; copy number 8: 50; copy number 9: 265; copy number 10: 86; copy number 17: 90; copy number 25: 5.

Homozygous deletions (total copy number 0; autosomes only): 3 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr11:109,637,468–109,638,128, 1 gene: AP003102.1.
- chr13:57,204,379–57,204,799, 1 gene: MTCO2P3.
- chr21:8,680,538–8,680,934, 1 gene: CR381572.2.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 513 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:38,239,580–38,340,998, 16 genes, copy number 9: TRGC2, TRGJP2, TRGC1, TRGJ1, TRGJP, TRGJP1, TRGV11, TRGVB, TRGV10, AC006033.1, TRGV9, TRGVA, AC006033.2, TRGV8, TRGV7, TRGV6.
- chr11:34,049,967–36,232,136, 39 genes, copy number 8–10: AC090469.1, CAPRIN1, NAT10, ABTB2, Y_RNA, MMADHCP2, AL035079.1, CIR1P3, CAT, ELF5, AL137224.1, LINC02707, EHF, AC087783.1, AL359999.1, APIP, PDHX, MIR1343, AL356215.1, CD44, CD44-AS1, AL133330.1, SLC1A2, SLC1A2-AS1, AC090625.1, AC090625.2, PAMR1, AL135934.1, FJX1, AL138812.1, TRIM44, KRT18P14, AC090692.1, LDLRAD3, AL136146.1, AL136146.2, RPL12P31, MIR3973, AC129502.1.
- chr11:60,835,996–61,161,615, 18 genes, copy number 8: AP000777.2, AP000777.3, CCDC86, PTGDR2, ZP1, PRPF19, AP003721.4, AP003721.3, TMEM109, AP003721.1, TMEM132A, SLC15A3, CD6, RNU6-933P, AP003721.2, CD5, VPS37C, AP000437.1.
- chr11:85,628,573–107,018,476, 363 genes, copy number 8–25 (broad region; genes not listed).
- chr14:21,990,496–22,511,024, 76 genes, copy number 7–10 (broad region; genes not listed).
- chr14:22,547,506–22,552,156, 1 gene, copy number 10: TRAC.

Autosomal genes at a single copy (total copy number 1): 685. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
